Somatic mutation profile of tumor specimen TCGA-DH-5141-01A (aliquot TCGA-DH-5141-01A-01D-1468-08) from TCGA case TCGA-DH-5141, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 32.4 years (11,846 days).
Specimen TCGA-DH-5141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eb0779b-14fa-42bb-803f-68a103c994dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-5141-10A (Blood Derived Normal), aliquot TCGA-DH-5141-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88348d5e-7d87-4e15-8a2a-40b827410e47

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- C5orf34 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 24/292 reads (8%) | catalogued as COSV60928950; called by muse, mutect2
- CATSPER1 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1319000804, COSV56409078, COSV56410960; called by muse, varscan2
- CHMP1A | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs773029258, COSV53682260; called by muse, mutect2, varscan2
- GBP5 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as rs1227430434, COSV58591492; called by muse, varscan2
- KLF4 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV65928586; called by muse, mutect2, varscan2
- KRT36 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs369076801; called by mutect2, varscan2
- LGR5 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 97/287 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs369268162; called by muse, mutect2, varscan2
- MIB2 | c.1130A>G p.K377R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.757); catalogued as rs1274279624, COSV61755055; called by muse, mutect2
- NCAM1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1555062963; called by muse, mutect2, varscan2
- NCKAP1L | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 227/691 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs879580819, COSV53205464; called by mutect2, varscan2
- NFIB | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101100382, COSV66620488; called by muse, mutect2
- NIPBL | c.4328C>G p.S1443* | Nonsense Mutation (SNP) | VAF 13/248 reads (5%) | catalogued as COSV56943061; called by muse, mutect2
- NLRP14 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs770545488, COSV55064325; called by muse, mutect2, varscan2
- PCARE | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV59053201; called by muse, mutect2, varscan2
- PCNX2 | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs1295898218, COSV50783177; called by muse, mutect2, varscan2
- PI4KA | c.2748G>A p.M916I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55404992; called by muse, mutect2
- PLXNB1 | c.2485C>G p.P829A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV56486844; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1382034089, COSV100365871; called by muse, mutect2
- RIF1 | c.1226C>A p.T409N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV54612726; called by muse, mutect2
- SERPINB3 | c.800T>G p.M267R | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV52189920; called by muse, mutect2, varscan2
- SPECC1L | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.581); catalogued as rs200267920, COSV58656608; called by muse, mutect2, varscan2
- CIC | c.3662_3663del p.S1221* | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- ADRB2 | c.528C>T p.A176= | Silent (SNP) | VAF 21/327 reads (6%) | catalogued as COSV60005229; called by muse, mutect2
- AHNAK | c.11907C>T p.D3969= | Silent (SNP) | VAF 49/665 reads (7%) | catalogued as rs762198506, COSV57204394; called by muse, mutect2
- CDH20 | c.924G>A p.E308= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as rs1190540052, COSV53005081; called by muse, mutect2, varscan2
- GRM1 | c.2484G>C p.G828= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as COSV51109689, COSV51298302; called by muse, mutect2
- PCSK2 | c.1032C>T p.D344= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs1193757704, COSV52726778, COSV52734911; called by muse, mutect2, varscan2
